Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GO, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GO-06A (Metastatic).

** Case imported from
** For cases prior to

. The format of this report does not match the original case. **
section "SPECIMEN" may have been added. **

DIAGNOSIS

(A) RIGHT AXILLARY CONTENTS LEVEL I, II AND III:
MALIGNANT MELANOMA METASTATIC TO EIGHTEEN OF TWENTY-FOUR LYMPH
NODES (18/24).
Largest tumor deposit 3.0 cm.
Extracapsular and vascular invasion present.

*ICDO-3
Melanoma NOS 8720/3
Site: Axillary lymph node
C77.3
W 11/27/13*

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) RIGHT AXILLARY CONTENTS LEVELS I, II, AND III, STITCH MARKS APEX OF
AXILLA - A portion of tan-yellow adipose tissue, 15.0 x 12.0 x 10.0 cm.
Multiple lymph nodes are identified within the specimen ranging from 0.4 to
3.0 cm in greatest dimension. Several of the lymph nodes including the
largest lymph nodes are grossly involved by metastatic tumor. The lymph node
at the apex is marked with a stitch.

SECTION CODE: A1, apical lymph node with stitch, bisected; A2-A3,
largest lymph node involved by tumor, representative; A4-A5, representative
section of node grossly involved by tumor; A6-A7, one lymph node, bisected;
A8, one lymph node bisected; A9-A15, one lymph node in each cassette; A16-A18,
multiple intact lymph nodes in each cassette.

SNOMED CODES

M-87206 T-C4710

-----END OF REPORT-----

HIVAA Discrepancy		✓

Source: NCI Genomic Data Commons file 33470b31-a33f-4eb1-b571-626aa65ac1d9 (TCGA-D3-A8GO.9BA4F56A-ED9D-4823-8F61-15CD1EE2F2D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).